Somatic mutation profile of tumor specimen MMRF_2013_1_BM_CD138pos (aliquot MMRF_2013_1_BM_CD138pos_T1_KHS5U_L08819) from MMRF case MMRF_2013, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.5 years (22,453 days).
Specimen MMRF_2013_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d9c3107-56fe-4b08-bbf0-c1b87d95270c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2013_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2013_1_PB_WBC_C3_KHS5U_L08802; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c2af90b-da59-4c4c-97ac-70ccdc89d365

The open-access MAF lists 93 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 18, Intron 16, Silent 13, 5'UTR 8, 5'Flank 5, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B3 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1428385982, COSV54840464; called by muse, mutect2, varscan2
- CTNNA3 | c.582C>G p.D194E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.165); catalogued as COSV65598758; called by muse, mutect2
- DCSTAMP | c.812A>C p.K271T | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs761365381; called by muse, mutect2, varscan2
- H1-5 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1414326744; called by muse, mutect2, varscan2
- IGLL5 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.112); catalogued as rs564743210, COSV73249743, COSV73250317, COSV73251309; called by muse, mutect2, varscan2
- IGLV3-1 | c.135A>C p.K45N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs183724895; called by muse, varscan2
- JHY | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs763403492, COSV56218045; called by muse, mutect2, varscan2
- LRP1B | c.13001C>A p.S4334* | Nonsense Mutation (SNP) | VAF 31/152 reads (20%) | catalogued as COSV67191718; called by muse, mutect2, varscan2
- LRRTM4 | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.201); catalogued as rs763423495; called by muse, mutect2, varscan2
- PI15 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs937194133, COSV52640621; called by muse, mutect2, varscan2
- PITPNC1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs780864654, COSV55447603; called by muse, mutect2, varscan2
- PLEKHG5 | c.2378C>T p.T793M (on ENST00000400915 / NM_001042663.3; = p.T756M on NM_020631.6) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781778550; called by muse, mutect2, varscan2
- SLTM | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 29/183 reads (16%) | catalogued as COSV100998859; called by muse, mutect2, varscan2
- SP8 | c.1415G>A p.C472Y (on ENST00000361443 / NM_198956.4; = p.C490Y on NM_182700.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1355142852; called by muse, mutect2, varscan2
- WDR6 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs552851712; called by muse, mutect2, varscan2
- ZNF521 | c.3507C>A p.N1169K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV100832574; called by muse, mutect2, varscan2
- ACTG1 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CACNA1G | c.6023A>G p.D2008G | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM193A | c.3320A>G p.N1107S | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HECW1 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IARS2 | c.2867T>G p.L956R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS4 | c.11A>T p.H4L | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LAPTM5 | c.401del p.F134Sfs*3 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by pindel, varscan2
- MMP2 | c.1016C>G p.T339S | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2
- PKHD1L1 | c.11585T>G p.L3862R | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R12A | c.49T>A p.W17R | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ROR1 | c.120A>C p.L40F | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPGRIP1 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- SFMBT2 | c.1808+2T>G p.X603_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2
- SIRPB2 | c.1010G>A p.W337* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- ZNF502 | c.1166C>T p.T389I | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.241); called by muse, mutect2
- ZNF814 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZNF99 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS12 | c.2091T>C p.D697= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs1470542438; called by muse, mutect2, varscan2
- ATP10B | c.3852T>C p.N1284= | Silent (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- CAPN9 | c.1173G>A p.Q391= | Silent (SNP) | VAF 28/91 reads (31%) | called by muse, mutect2, varscan2
- EMCN | c.309A>G p.S103= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- FLT4 | c.2256C>T p.N752= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs986151831, COSV56112283; called by muse, mutect2, varscan2
- LOXHD1 | c.6699G>A p.L2233= (on ENST00000642948; = p.L2171= on NM_144612.7) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1218049916; called by muse, mutect2, varscan2
- MCCC1 | c.1773C>T p.S591= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as rs200651846, COSV99659650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOX4 | c.1566A>T p.G522= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV54458962; called by muse, mutect2, varscan2
- OBSL1 | c.4896G>A p.V1632= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- PBX2 | c.561G>A p.T187= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs532139709; called by muse, mutect2, varscan2
- PKD1L3 | c.2397T>A p.T799= | Silent (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- PTPRE | c.240C>T p.S80= | Silent (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- ZNF200 | c.681T>C p.P227= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- ACTG1 | c.363+73A>G | Intron (SNP) | VAF 16/58 reads (28%) | catalogued as rs1171235076; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65497944 T>C | 5'Flank (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498042 T>G | 5'Flank (SNP) | VAF 55/119 reads (46%) | called by muse, mutect2, varscan2
- ATG10 | c.217-16638A>G | Intron (SNP) | VAF 23/135 reads (17%) | catalogued as rs539902647; called by muse, mutect2, varscan2
- CALML3 | c.-119G>A | 5'UTR (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100178814; called by muse, mutect2, varscan2
- CCDC50 | c.-223G>A | 5'UTR (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- CELF2 | c.1076-2629A>G | Intron (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- CHL1 | c.*249C>A | 3'UTR (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- CPD | c.*316C>A | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- DGKB | c.-81A>C | 5'UTR (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- FAM122A | c.*1337C>G | 3'UTR (SNP) | VAF 18/90 reads (20%) | catalogued as rs1224867703, COSV99599711; called by muse, mutect2, varscan2
- GAB2 | c.*2393C>T | 3'UTR (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- GCNT2 | c.925+143A>C | Intron (SNP) | VAF 6/13 reads (46%) | called by muse, varscan2
- GPR132 | c.-101G>A | 5'UTR (SNP) | VAF 70/169 reads (41%) | called by muse, mutect2, varscan2
- GRHL2 | c.*927C>A | 3'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- GRIN3A | c.-27C>A | 5'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- GRIP1 | c.-145T>A | 5'UTR (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- HGF | c.*3510T>G | 3'UTR (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2
- HLA-DPB1 | c.-9T>C | 5'UTR (SNP) | VAF 20/524 reads (4%) | called by muse, mutect2
- LARS1 | c.1656-22T>C | Intron (SNP) | VAF 68/184 reads (37%) | called by muse, mutect2, varscan2
- LTB | c.163-37A>G | Intron (SNP) | VAF 157/411 reads (38%) | catalogued as rs1166248275, COSV53002626; called by muse, mutect2, varscan2
- MFRP | chr11:119346275 G>A | 5'Flank (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- MIOX | c.341-12T>C | Intron (SNP) | VAF 6/74 reads (8%) | catalogued as rs1266275931; called by muse, mutect2
- MIR5195 | chr14:106851255 A>T | 5'Flank (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- MMP16 | c.*4905G>T | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- MYLK | c.5239-2992T>A | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1254G>T | 3'UTR (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-680T>G | Intron (SNP) | VAF 66/143 reads (46%) | called by muse, mutect2, varscan2
- OSBPL8 | c.*1439G>A | 3'UTR (SNP) | VAF 5/53 reads (9%) | catalogued as rs191966849; called by mutect2, varscan2
- PAX2 | c.44-406G>A | Intron (SNP) | VAF 102/222 reads (46%) | called by muse, mutect2, varscan2
- PCSK2 | c.*1714A>G | 3'UTR (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+4071T>A | Intron (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- PDPN | c.*1149G>C | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- PLG | c.407+48C>A | Intron (SNP) | VAF 30/365 reads (8%) | called by muse, mutect2
- PUF60 | c.349-31C>T | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2
- RDX | c.1748+1931_1748+1932del | Intron (DEL) | VAF 59/290 reads (20%) | called by mutect2, pindel, varscan2
- RGS5 | c.*1628A>G | 3'UTR (SNP) | VAF 49/103 reads (48%) | catalogued as rs990908184; called by muse, mutect2, varscan2
- SCAF8 | c.-422T>G | 5'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- SEC24C | c.*926A>C | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- SEC62 | chr3:169966790 C>T | 5'Flank (SNP) | VAF 13/57 reads (23%) | catalogued as rs745564509; called by muse, mutect2, varscan2
- SLC24A4 | c.*2450C>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs915843462; called by muse, mutect2, varscan2
- STPG1 | c.*696G>A | 3'UTR (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2
- TMEM120B | c.*722+93G>A | Intron (SNP) | VAF 42/71 reads (59%) | catalogued as rs1258727853; called by muse, mutect2, varscan2
- UBE3C | c.*627A>G | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- USP11 | c.1150-36T>A | Intron (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- ZMAT2 | c.*283G>C | 3'UTR (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- ZNF385D | c.*1702G>T | 3'UTR (SNP) | VAF 3/47 reads (6%) | catalogued as rs1385605404; called by muse, mutect2
